Gene-level copy-number profile of tumor specimen TCGA-IB-7889-01A from TCGA case TCGA-IB-7889, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 85.9 years (31,393 days).
Specimen TCGA-IB-7889-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.e5f786b8-9960-4b16-b981-ab9e80661822.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-7889-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/303498ef-c96d-4436-8c1e-6fc91f0f0afe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,698; copy number 2: 35,960; copy number 3: 12,835; copy number 4: 1,279; copy number 6: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-7889-01A-11D-2153-01): tumor purity 0.19, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:17,476,994–17,512,266, 3 genes, copy number 6: MED9, RASD1, AC020558.6.
- chr17:17,507,351–17,508,308, 1 gene, copy number 6: AC020558.2.
- chr17:18,087,892–18,644,427, 39 genes, copy number 6: DRG2, AC087164.2, MYO15A, AC087164.1, ALKBH5, LLGL1, FLII, MIEF2, AC127537.1, TOP3A, RPL7AP65, RPL21P121, SMCR8, SHMT1, MIR6778, EVPLL, AL353997.2, AL353997.3, AL353997.5, TBC1D3P4, LINC02076, KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2, CCDC144B, AC107983.1, Metazoa_SRP, TBC1D28, AC026271.2.

Autosomal genes at a single copy (total copy number 1): 9,698. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
